TARGET case TARGET-52-PAWFWK — Rhabdoid Tumor (TARGET-RT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e0815ea1-1ecd-5c27-81cf-e8ed93fa5fbf

Demographics
Sex at birth: male; Race: white; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Malignant rhabdoid tumor: ICD-O-3 morphology code: 8963/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 0.6 years (231 days); Year of diagnosis: 2014; Days to last follow up: 992 days (2.7 years); Pediatric kidney staging: Tumor biopsied only at diagnosis, no distant metastasis.
   Treatment given: Protocol identifier: AREN03B2.

Follow-up (1 entry)
- Days to follow up: 992 days (2.7 years); Event-free: no event (relapse, second malignancy or death) recorded through day 992; Year of follow up: 2017.

Molecular and laboratory tests
- SMARCB1 deletion: Positive.

Biospecimens (2 samples)
- Sample TARGET-52-PAWFWK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-52-PAWFWK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Discovery_and_Validation_Supplement_20230322.xlsx, for sample TARGET-52-PAWFWK-01A-01D:
- Cohort: Validation
- Tumour content estimated by APOLLOH (%): 93.84
- Anatomical site of matched normal: Peripheral blood
- Stage of the primary tumour at the time of diagnosis: 3
- INImutationfound?: Yes
- Type of mutation in tumor: Alteration 1 whole gene deletion; Alteration 2 whole gene deletion

Additional fields from the TARGET clinical supplement workbook TARGET_RT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 992
- Stage: IIIB
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: RT
